Somatic mutation profile of tumor specimen C3N-00149-04 (aliquot CPT0084580009) from CPTAC case C3N-00149, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.4 years (24,990 days).
Specimen C3N-00149-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3272b1e2-6cb9-4059-9879-faeedc90d446.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00149-31 (Blood Derived Normal), aliquot CPT0085310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e7338c5-6dc5-4fd3-93bb-a2b42c038704

The open-access MAF lists 95 somatic variants for this specimen: 67 protein-altering or splice-affecting, 14 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 14, Frame Shift Del 10, Intron 8, RNA 2, Nonsense Mutation 2, Splice Site 2, 5'UTR 2, Frame Shift Ins 1, 5'Flank 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 172/562 reads (31%) | catalogued as rs5030829, CM156382, CM941369, COSV56543353, COSV56543426; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APOB | c.12531del p.V4178Lfs*7 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as COSV51938628; called by mutect2, pindel, varscan2
- ATP6V0A2 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 88/472 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1295585374, COSV100376830; called by muse, mutect2, varscan2
- DENND4A | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); catalogued as rs1350242757; called by muse, mutect2
- DMD | c.6862C>A p.Q2288K | Missense Mutation (SNP) | VAF 79/394 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs967525950, CM103845; called by muse, mutect2, varscan2
- IGSF22 | c.1533G>A p.E511= | Splice Region (SNP) | VAF 31/170 reads (18%) | catalogued as rs1412949342; called by muse, mutect2, varscan2
- INTS8 | c.520A>G p.M174V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1311719361; called by muse, mutect2, varscan2
- MMP17 | c.1059C>A p.Y353* | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | catalogued as rs1314106394; called by muse, mutect2, varscan2
- OLIG1 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs1457760135, COSV60737713; called by muse, varscan2
- PCMTD1 | c.121T>A p.Y41N | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV62124592; called by muse, mutect2, varscan2
- RBM48 | c.731del p.L244Cfs*6 | Frame Shift Del (DEL) | VAF 38/256 reads (15%) | catalogued as rs770281416; called by mutect2, pindel, varscan2
- SEMA5B | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV99533137; called by muse, mutect2, varscan2
- TGFBR2 | c.1583G>T p.R528L | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM050762, CM159806, COSV55442586, COSV55450248; called by muse, mutect2, varscan2
- TRPC7 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs536224426; called by muse, mutect2, varscan2
- TTI1 | c.293del p.S98* | Frame Shift Del (DEL) | VAF 37/281 reads (13%) | catalogued as COSV65060289, COSV65063743; called by mutect2, pindel, varscan2
- ABL1 | c.3016A>C p.I1006L | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ATP6V0A2 | c.497_521+3del | Frame Shift Del (DEL) | VAF 20/210 reads (10%) | called by mutect2, pindel
- BAP1 | c.2057-1G>C p.X686_splice | Splice Site (SNP) | VAF 89/287 reads (31%) | called by muse, mutect2, varscan2
- BSG | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C3 | c.4187A>T p.Q1396L | Missense Mutation (SNP) | VAF 38/384 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2
- CALR | c.35_45del p.L12Rfs*44 | Frame Shift Del (DEL) | VAF 92/564 reads (16%) | called by mutect2, pindel, varscan2
- CCDC63 | c.1108T>G p.L370V | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CDC42EP4 | c.973T>C p.F325L | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH11 | c.406A>T p.N136Y | Missense Mutation (SNP) | VAF 85/543 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CPEB4 | c.535T>C p.S179P | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2
- DENND4A | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.965); called by muse, mutect2
- DLC1 | c.3167+1G>A p.X1056_splice (on ENST00000276297 / NM_001348081.2; = p.X619_splice on NM_006094.5) | Splice Site (SNP) | VAF 10/72 reads (14%) | called by mutect2, varscan2
- DTNB | c.1430C>A p.T477K | Missense Mutation (SNP) | VAF 80/315 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- EIF2AK1 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- EXPH5 | c.3443del p.D1148Vfs*5 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- FAM126B | c.695T>G p.L232W | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FER1L5 | c.5717A>T p.K1906M (on ENST00000623019; = p.K1870M on NM_001293083.2) | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2
- FYB1 | c.1053T>A p.F351L | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GCG | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2
- GRM1 | c.2647del p.A883Qfs*35 | Frame Shift Del (DEL) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- GTSE1 | c.1569C>G p.S523R | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- HIPK1 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- HK1 | c.2390T>C p.L797P | Missense Mutation (SNP) | VAF 79/463 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ICE1 | c.3739A>T p.N1247Y | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- IL4R | c.833T>C p.I278T | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ITGB1BP2 | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPK8IP3 | c.3641G>T p.R1214M | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- MED15 | c.1699A>G p.K567E (on ENST00000263205 / NM_001003891.3; = p.K527E on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYDGF | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- N4BP2L2 | c.2665A>G p.I889V (on ENST00000674422; = p.I460V on NM_033111.4) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NAV2 | c.1418C>A p.T473N (on ENST00000396087 / NM_001244963.2; = p.T450N on NM_145117.5) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2
- NBEAL1 | c.1869del p.F623Lfs*46 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | called by mutect2, pindel
- NDUFAF7 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- NIPBL | c.96_120del p.L32Ffs*7 | Frame Shift Del (DEL) | VAF 23/243 reads (9%) | called by mutect2, pindel
- NUCKS1 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OS9 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PCDHA12 | c.1654C>A p.Q552K | Missense Mutation (SNP) | VAF 32/1092 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); called by muse, mutect2
- PIK3R3 | c.758T>A p.I253N | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- PORCN | c.316T>C p.Y106H | Missense Mutation (SNP) | VAF 11/349 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PRDX1 | c.267dup p.T90Yfs*3 | Frame Shift Ins (INS) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- PRMT3 | c.1393A>T p.N465Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PYGM | c.31del p.R11Efs*15 | Frame Shift Del (DEL) | VAF 26/162 reads (16%) | called by mutect2, pindel
- RSU1 | c.299C>G p.T100S | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- RXRB | c.1016T>C p.I339T | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SAMM50 | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by mutect2, varscan2
- SAP30BP | c.616A>T p.I206F | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.319); called by muse, mutect2
- SPINK5 | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 72/465 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- STAB1 | c.4184A>T p.Q1395L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMC7 | c.2114G>T p.R705L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- TRO | c.2554A>T p.T852S | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF532 | c.3383A>T p.E1128V | Missense Mutation (SNP) | VAF 54/279 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ZNF644 | c.3646T>G p.L1216V | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ADRA1D | c.726C>T p.D242= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs764832183, COSV101062924, COSV65241656; called by muse, mutect2
- BFAR | c.150G>T p.G50= | Silent (SNP) | VAF 90/474 reads (19%) | called by muse, mutect2, varscan2
- CYRIB | c.267A>G p.K89= | Silent (SNP) | VAF 32/153 reads (21%) | called by muse, mutect2, varscan2
- DOCK2 | c.1872T>C p.R624= | Silent (SNP) | VAF 54/164 reads (33%) | called by muse, mutect2, varscan2
- LTN1 | c.2481C>T p.A827= | Silent (SNP) | VAF 36/144 reads (25%) | called by muse, mutect2, varscan2
- NBEAL1 | c.1675C>A p.R559= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV101495615; called by muse, mutect2, varscan2
- NME4 | c.468G>A p.V156= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as rs751493049; called by muse, mutect2, varscan2
- OBSCN | c.10932G>A p.V3644= | Silent (SNP) | VAF 63/318 reads (20%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1575C>T p.H525= | Silent (SNP) | VAF 64/1157 reads (6%) | catalogued as COSV65324866; called by muse, mutect2
- PIWIL4 | c.1782G>A p.K594= | Silent (SNP) | VAF 60/322 reads (19%) | called by muse, mutect2, varscan2
- SDHAF2 | c.213C>T p.L71= | Silent (SNP) | VAF 56/316 reads (18%) | called by muse, mutect2, varscan2
- TMC7 | c.2115T>G p.R705= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- ZNHIT2 | c.183C>T p.P61= | Silent (SNP) | VAF 21/113 reads (19%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.1593C>G p.R531= (on ENST00000252463; = p.R586= on NM_032805.3) | Silent (SNP) | VAF 52/276 reads (19%) | called by muse, mutect2, varscan2
- CRYM | c.674-34T>C | Intron (SNP) | VAF 61/368 reads (17%) | called by muse, mutect2, varscan2
- KLF3-AS1 | n.702+830C>T | Intron (SNP) | VAF 12/89 reads (13%) | catalogued as rs1048716567; called by muse, mutect2, varscan2
- MOG | c.731-218G>A | Intron (SNP) | VAF 52/224 reads (23%) | called by muse, mutect2, varscan2
- NBPF7 | n.867C>G | RNA (SNP) | VAF 42/216 reads (19%) | catalogued as rs1171243133; called by muse, mutect2, varscan2
- NBPF9 | c.2476+731G>T | Intron (SNP) | VAF 49/275 reads (18%) | called by muse, mutect2, varscan2
- PPP1R3B | chr8:9155039 del A | 5'Flank (DEL) | VAF 24/128 reads (19%) | called by mutect2, pindel, varscan2
- RAD23A | c.-73C>T | 5'UTR (SNP) | VAF 40/186 reads (22%) | catalogued as rs960563311; called by muse, mutect2, varscan2
- RRP7A | c.217-109G>A | Intron (SNP) | VAF 35/185 reads (19%) | called by muse, mutect2, varscan2
- RYR3 | c.10023+9C>A | Intron (SNP) | VAF 18/182 reads (10%) | called by muse, mutect2
- SH2D6 | n.652G>A | RNA (SNP) | VAF 32/311 reads (10%) | catalogued as rs755907033, COSV61064383; called by muse, mutect2, varscan2
- SPEF2 | c.4448-3461C>T | Intron (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- SYTL5 | c.1155+610G>A | Intron (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- UBR7 | c.*426T>G | 3'UTR (SNP) | VAF 118/424 reads (28%) | called by muse, mutect2, varscan2
- VLDLR | c.-380G>T | 5'UTR (SNP) | VAF 54/146 reads (37%) | called by muse, mutect2, varscan2
